CCDI case PBCAVJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Specialized Gonadal Neoplasms; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/67202077-6787-4cae-a16c-05405577feab

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Sex cord-gonadal stromal tumor, NOS: ICD-O-3 morphology code: 8590/1; Tissue or organ of origin: Ovary; Age at diagnosis: 5.6 years (2,045 days).

Biospecimens (3 samples)
- Sample 0DMUY2: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DMUZG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DMWU0: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
